Somatic mutation profile of tumor specimen TCGA-06-6697-01A (aliquot TCGA-06-6697-01A-11D-1845-08) from TCGA case TCGA-06-6697, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,763 days).
Specimen TCGA-06-6697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11f40b02-24b1-4548-98c7-32d19172d7a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6697-10A (Blood Derived Normal), aliquot TCGA-06-6697-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d8a690c-503b-4db2-9c6d-129a12001917

The open-access MAF lists 68 somatic variants for this specimen: 55 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 10, Nonsense Mutation 3, Intron 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.2385G>A p.M795I | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as COSV55933735, COSV99711637; called by muse, mutect2, varscan2
- ACAD11 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53894959; called by muse, mutect2, varscan2
- ARHGAP35 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68330115; called by muse, mutect2, varscan2
- ATP11B | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60027382; called by muse, mutect2, varscan2
- CDH23 | c.8500G>A p.V2834I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs190672679, COSV56455016; called by muse, mutect2, varscan2
- CDYL2 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.368); catalogued as COSV73647597; called by muse, mutect2, varscan2
- CELSR3 | c.7021C>T p.R2341C | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1003465663, COSV50839665; called by muse, mutect2, varscan2
- CHD9 | c.2942G>T p.G981V | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54609043; called by muse, mutect2
- CLEC7A | c.466C>G p.L156V (on ENST00000304084 / NM_197947.3; = p.L110V on NM_022570.5) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV53721823; called by muse, mutect2, varscan2
- CRB1 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100958375, COSV66338693; called by muse, mutect2, varscan2
- DCAF12L2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs756958968, COSV63580290; called by muse, mutect2, varscan2
- DCLRE1B | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.338); catalogued as rs1307806966, COSV65812447; called by muse, mutect2, varscan2
- DGKD | c.2276C>G p.T759R (on ENST00000264057 / NM_152879.3; = p.T715R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV51037705; called by muse, mutect2
- DNAH5 | c.12644C>T p.A4215V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs200969063, COSV54214823; called by muse, mutect2, varscan2
- DNAJC13 | c.4159T>A p.L1387I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53448071; called by muse, mutect2, varscan2
- DSP | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs758592774, COSV65792105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVI2B | c.418A>C p.K140Q | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV58363652; called by muse, mutect2
- FAP | c.738A>T p.R246S | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV51860550; called by muse, mutect2, varscan2
- FILIP1 | c.2025C>G p.N675K | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.01); catalogued as COSV52726195; called by muse, mutect2, varscan2
- GCSAML | c.11A>T p.Y4F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.198); catalogued as COSV63577406; called by muse, mutect2, varscan2
- IGFN1 | c.2665C>T p.L889F (on ENST00000295591 / NM_001367841.1; = p.L3346F on NM_001164586.2) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as COSV55169332; called by muse, mutect2, varscan2
- IRF1 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.154); catalogued as COSV55376784; called by muse, mutect2, varscan2
- KCNH8 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV60459978; called by muse, mutect2, varscan2
- LZTR1 | c.416A>C p.D139A | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53146351; called by muse, mutect2
- MMP27 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs766084332, COSV52780235; called by muse, mutect2, varscan2
- MPL | c.1649G>A p.S550N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as rs1419808054, COSV65244506; called by muse, mutect2, varscan2
- MYO18B | c.5926G>C p.E1976Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59129980; called by muse, mutect2
- MYOF | c.3059G>A p.R1020Q | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761738450, COSV63702126, COSV63705079; called by muse, mutect2, varscan2
- NBEAL2 | c.4097G>T p.G1366V | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.331); catalogued as COSV52755997; called by muse, mutect2, varscan2
- NCOA2 | c.2620C>T p.R874* | Nonsense Mutation (SNP) | VAF 54/153 reads (35%) | catalogued as rs768636250, COSV51218766; called by muse, mutect2, varscan2
- NRG4 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201119503, COSV59638001; called by muse, mutect2, varscan2
- OR10A3 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.155); catalogued as rs539222840, COSV62459345; called by muse, mutect2, varscan2
- OR10C1 | c.817C>A p.P273T (on ENST00000622521; = p.P271T on NM_013941.3) | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs200438931, COSV65822483; called by muse, mutect2
- OR51V1 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58314763; called by muse, mutect2, varscan2
- PCDH11Y | c.3965G>A p.R1322H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as COSV53078087; called by muse, mutect2, varscan2
- PCLO | c.10015G>T p.G3339C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61625154, COSV61633753; called by muse, mutect2, varscan2
- PCSK2 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); catalogued as rs567308071, COSV52729317; called by muse, mutect2, varscan2
- PEX12 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV56777825; called by muse, mutect2, varscan2
- PHF20L1 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55190517; called by muse, mutect2, varscan2
- PIK3CG | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs373006568; called by muse, mutect2
- POGLUT3 | c.1403A>T p.Y468F | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV60212110; called by muse, mutect2, varscan2
- SLC44A2 | c.1625C>T p.T542I | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV59835839; called by muse, mutect2, varscan2
- SMC1B | c.3103C>G p.Q1035E | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV62529039; called by muse, mutect2, varscan2
- SPEN | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65359857; called by muse, mutect2, varscan2
- SRRM2 | c.2174G>A p.G725D | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57070853; called by muse, mutect2, varscan2
- SYCP2 | c.3682C>T p.R1228W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); catalogued as rs770144840, COSV62766165; called by muse, mutect2, varscan2
- TEX14 | c.553G>T p.G185* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV53614235; called by muse, mutect2, varscan2
- TIMM44 | c.518C>A p.T173K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV54490827; called by muse, mutect2, varscan2
- TLR5 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs200696063, COSV60558441; called by muse, mutect2, varscan2
- WASHC4 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs372217243; called by muse, mutect2, varscan2
- ZNF282 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.805); catalogued as rs1345393912, COSV50479435; called by muse, mutect2
- ZNF570 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.953); catalogued as rs146360083, COSV57578593; called by muse, mutect2, varscan2
- ZNF709 | c.1265G>A p.C422Y | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67194424, COSV67196094; called by muse, varscan2
- DARS1 | c.565-6_569del p.X189_splice | Splice Site (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- ZNF318 | c.3664_3665del p.E1222Sfs*5 | Frame Shift Del (DEL) | VAF 50/287 reads (17%) | called by mutect2, pindel, varscan2
- DAB1 | c.1341G>A p.T447= (on ENST00000371231; = p.T414= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs147876561; called by muse, mutect2, varscan2
- DHRS9 | c.351C>T p.G117= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs770007864, COSV59139316; called by muse, mutect2, varscan2
- KLRC2 | c.234C>A p.I78= | Silent (SNP) | VAF 49/447 reads (11%) | catalogued as COSV67899651; called by muse, mutect2, varscan2
- KRTAP10-7 | c.759A>C p.P253= | Silent (SNP) | VAF 52/254 reads (20%) | catalogued as COSV59109852; called by muse, mutect2, varscan2
- LRRIQ1 | c.2538T>C p.D846= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV67828212; called by muse, mutect2, varscan2
- OR1S1 | c.672T>C p.F224= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV58706626; called by muse, mutect2
- PRAMEF2 | c.216G>A p.T72= | Silent (SNP) | VAF 62/313 reads (20%) | catalogued as rs766631112, COSV53574105; called by muse, mutect2, varscan2
- SDK1 | c.2160C>T p.N720= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs747949026, COSV67362386; called by muse, mutect2, varscan2
- SECISBP2 | c.2436G>A p.L812= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV59393135; called by muse, mutect2, varscan2
- TTN | c.14229C>T p.V4743= (on ENST00000591111; = p.V3816= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/247 reads (26%) | catalogued as rs376217206; ClinVar: likely benign; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827708 A>T | 3'Flank (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*3801T>G | 3'UTR (SNP) | VAF 13/48 reads (27%) | catalogued as COSV57056300; called by muse, mutect2, varscan2
- CR2 | c.1979-218A>G | Intron (SNP) | VAF 32/144 reads (22%) | catalogued as COSV100889539; called by muse, mutect2
